TCGA case TCGA-B8-4143 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dfa9513d-4e09-405b-a80f-2987ec5c5263

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 709 days (1.9 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.1 years (24,132 days); Year of diagnosis: 2002; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interleukin-2; Initial disease status: Progressive Disease; Days to treatment start: 133 days; Days to treatment end: 388 days (1.1 years); Number of cycles: 3; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 477 days (1.3 years); Days to treatment end: 508 days (1.4 years); Course number: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 600 days (1.6 years); Days to treatment end: 630 days (1.7 years); Course number: 2; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 436 days (1.2 years); Treatment anatomic sites: Distant Site.

Follow-up (3 entries)
- Days to follow up: 709 days (1.9 years); Disease response: With Tumor.
- Karnofsky performance status: 0; Timepoint: Other.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Normal.
- Calcium: Elevated.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B8-4143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-B8-4143-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-B8-4143-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-B8-4143-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B8-4143-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.7; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Interleukin-2; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Metastatic disease at diagnosis.
- Drug treatment, Route of administrations: Route of administration: IV.
- Radiation treatment 1: Therapy regimen: Progression.
- Follow-up form: Tumor status: With tumor; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 709 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 709 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 709 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B8-4143-01A-01D-1185-01): tumor purity 0.44, ploidy 3.83, whole-genome doublings 1.
